Somatic mutation profile of tumor specimen TCGA-AY-6386-01A (aliquot TCGA-AY-6386-01A-21D-1719-10) from TCGA case TCGA-AY-6386, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 66.9 years (24,453 days).
Specimen TCGA-AY-6386-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bdef23a-99c4-46ce-9629-415542474d94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-6386-10A (Blood Derived Normal), aliquot TCGA-AY-6386-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c89922c-1e2f-4705-b59a-04f710800868

The open-access MAF lists 121 somatic variants for this specimen: 90 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 30, Nonsense Mutation 12, Frame Shift Ins 5, Splice Site 5, Frame Shift Del 3, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 25/93 reads (27%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 30/724 reads (4%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 42/120 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 212/696 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCK1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as rs766848926, COSV53083782; called by muse, mutect2, varscan2
- ALDH1A2 | c.902-2A>G p.X301_splice | Splice Site (SNP) | VAF 14/106 reads (13%) | catalogued as COSV51087444; called by muse, mutect2, varscan2
- AMER1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 121/376 reads (32%) | catalogued as COSV57655167; called by muse, mutect2, varscan2
- APC | c.2291T>G p.L764* | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as CM130056, CM990153, COSV57366985, COSV57390091; called by muse, mutect2, varscan2
- ARHGAP4 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 97/315 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs368931061, COSV61686690; called by muse, mutect2, varscan2
- ATP10A | c.3163C>T p.Q1055* | Nonsense Mutation (SNP) | VAF 78/248 reads (31%) | catalogued as COSV63521223; called by muse, mutect2, varscan2
- BTG4 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 106/304 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764916472, COSV63636511; called by muse, mutect2, varscan2
- CCDC163 | c.431G>T p.C144F | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as COSV100517590; called by muse, mutect2, varscan2
- COL27A1 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs774381208, COSV61929452; called by muse, mutect2, varscan2
- COL6A3 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs575412915, COSV55101444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLQ | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1167974168, COSV67525499; called by muse, mutect2, varscan2
- CSMD2 | c.7961G>A p.R2654Q | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1000408473, COSV53942325, COSV53971497; called by muse, mutect2, varscan2
- CSRNP3 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs543669496, COSV58775683; called by muse, mutect2, varscan2
- DCAF1 | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 141/454 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV60045434; called by muse, mutect2, varscan2
- DMC1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 47/119 reads (39%) | catalogued as rs1300163639, COSV53258029; called by muse, mutect2, varscan2
- ECHS1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs745362960, COSV63907156; called by muse, mutect2, varscan2
- EMID1 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 110/295 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.528); catalogued as COSV61830419; called by muse, mutect2, varscan2
- FAT4 | c.13715C>T p.T4572I | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV100629478; called by muse, mutect2, varscan2
- G3BP1 | c.1088A>G p.Y363C | Missense Mutation (SNP) | VAF 143/448 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100664021; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); catalogued as COSV61323881; called by muse, mutect2, varscan2
- GPBP1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766026442, COSV53309762; called by muse, mutect2, varscan2
- GPC5 | c.773G>T p.C258F | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65617647; called by muse, mutect2, varscan2
- GYPC | c.189A>T p.A63= | Splice Region (SNP) | VAF 62/182 reads (34%) | catalogued as COSV52145902, COSV52147915; called by muse, mutect2, varscan2
- H3C13 | c.25C>A p.R9S | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV58944683, COSV58944907; called by muse, mutect2, varscan2
- HAT1 | c.569G>C p.S190T | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.569); catalogued as COSV51364635; called by muse, mutect2, varscan2
- HERC6 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.146); catalogued as rs375413927, COSV52032221; called by muse, mutect2, varscan2
- HRH2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 135/367 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs774838699, COSV51574002, COSV51574698; called by muse, mutect2, varscan2
- IL2RG | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.314); catalogued as CD951748, COSV52149675; called by muse, mutect2, varscan2
- JMJD1C | c.3530C>A p.T1177K | Missense Mutation (SNP) | VAF 127/365 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.108); catalogued as COSV59517070; called by muse, mutect2, varscan2
- KCTD11 | c.217C>T p.R73W (on ENST00000333751 / NM_001363642.1; = p.R34W on NM_001002914.2) | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs781114097, COSV50135356; called by muse, mutect2, varscan2
- KLC2 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.885); catalogued as rs373644165; called by muse, mutect2, varscan2
- KMT2B | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs773862731, COSV52891879; called by muse, mutect2, varscan2
- LAMB4 | c.591+1G>A p.X197_splice | Splice Site (SNP) | VAF 40/185 reads (22%) | catalogued as COSV52726498; called by muse, mutect2, varscan2
- LRCH2 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV57756781; called by muse, mutect2, varscan2
- MUC16 | c.41863G>A p.V13955I | Missense Mutation (SNP) | VAF 102/355 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.855); catalogued as rs756887648, COSV66695154; called by muse, mutect2, varscan2
- MUC16 | c.40052C>T p.T13351M | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs369380417; called by muse, mutect2, varscan2
- NALCN | c.5022A>G p.S1674= | Splice Region (SNP) | VAF 22/85 reads (26%) | catalogued as COSV51954028; called by muse, mutect2, varscan2
- NPAP1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs762414613, COSV61509742, COSV61512793; called by muse, mutect2, varscan2
- NUP205 | c.4246C>T p.R1416* | Nonsense Mutation (SNP) | VAF 122/234 reads (52%) | catalogued as COSV99607353; called by muse, mutect2, varscan2
- PABPC5 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV100442599; called by muse, mutect2
- PASD1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV64856822; called by muse, mutect2, varscan2
- PEBP1 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs768506934, COSV99732018; called by muse, mutect2
- PHF20 | c.1930G>A p.G644R | Missense Mutation (SNP) | VAF 89/304 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as COSV59187834; called by muse, mutect2, varscan2
- PIK3AP1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.437); catalogued as rs182619826, COSV59535309; called by muse, mutect2, varscan2
- PKLR | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as rs971962553, COSV61360923; called by muse, mutect2, varscan2
- PLPPR4 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV64570496; called by muse, mutect2, varscan2
- PLXNA3 | c.2845G>A p.G949R | Missense Mutation (SNP) | VAF 104/330 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs782070642, COSV63753133; called by muse, mutect2, varscan2
- PTCHD1 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 107/336 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV65062023; called by muse, mutect2, varscan2
- PTPRT | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs547641233, COSV62005182, COSV62012587; called by muse, mutect2, varscan2
- RAPGEF3 | c.2747G>A p.R916H (on ENST00000389212; = p.R874H on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs1211348676, COSV50224969; called by muse, varscan2
- RGMB | c.1265T>A p.L422* (on ENST00000513185 / NM_001366508.1; = p.L463* on NM_001012761.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 97/280 reads (35%) | catalogued as COSV57566515; called by muse, mutect2, varscan2
- RHOBTB1 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.368); catalogued as rs138580713, COSV61957775; called by muse, mutect2, varscan2
- SATB2 | c.1226A>G p.Q409R | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV53490080; called by muse, mutect2, varscan2
- SEL1L2 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53155769; called by muse, mutect2, varscan2
- SEMA4F | c.1948C>T p.R650* | Nonsense Mutation (SNP) | VAF 69/206 reads (33%) | catalogued as rs142022737, COSV60283484; called by muse, mutect2, varscan2
- SEPTIN8 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as COSV51524723; called by muse, mutect2, varscan2
- SETD5 | c.4159C>T p.R1387W | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs560529972, COSV56710136; called by muse, mutect2, varscan2
- SLC25A48 | c.470C>T p.A157V (on ENST00000650267; = p.A103V on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99192081; called by muse, mutect2, varscan2
- SLC5A3 | c.1282A>G p.I428V | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs780017963, COSV62972188; called by muse, mutect2, varscan2
- SMAD4 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 71/158 reads (45%) | catalogued as COSV61688931; called by muse, mutect2, varscan2
- SPANXN3 | c.79-1G>C p.X27_splice | Splice Site (SNP) | VAF 10/251 reads (4%) | catalogued as COSV100980835, COSV65140521, COSV65140574; called by muse, mutect2
- SPANXN3 | c.71dup p.N24Kfs*2 | Frame Shift Ins (INS) | VAF 199/695 reads (29%) | catalogued as rs781940283; called by mutect2, varscan2
- TEX14 | c.1516A>G p.I506V (on ENST00000240361 / NM_001201457.2; = p.I500V on NM_031272.5) | Missense Mutation (SNP) | VAF 135/409 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53623025; called by muse, mutect2, varscan2
- TGIF2LX | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs1341625302, COSV52214806; called by muse, mutect2, varscan2
- THAP9 | c.580+2T>C p.X194_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56357235; called by mutect2, varscan2
- TMEM132D | c.1792C>A p.L598M | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67161654; called by muse, mutect2, varscan2
- TMPRSS11D | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1237417289, COSV52225171; called by muse, mutect2, varscan2
- TMPRSS15 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs146494364, COSV53038195; called by muse, mutect2, varscan2
- TRIM51 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 355/1148 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55269335; called by muse, mutect2, varscan2
- UNC13A | c.4738G>A p.D1580N | Missense Mutation (SNP) | VAF 54/331 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as rs770973163, COSV53204994; called by muse, mutect2, varscan2
- URI1 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 41/134 reads (31%) | catalogued as rs771563788, COSV56352220, COSV56353449; called by muse, mutect2, varscan2
- VAV1 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV58388629; called by muse, mutect2, varscan2
- XPO4 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 78/189 reads (41%) | catalogued as COSV55011137; called by muse, mutect2, varscan2
- YLPM1 | c.5477C>T p.P1826L | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs776882142, COSV53117540; called by muse, mutect2, varscan2
- ZCCHC3 | c.951C>A p.F317L | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.259); catalogued as COSV66643620; called by muse, mutect2, varscan2
- ZFHX4 | c.7378G>A p.G2460R | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.07); catalogued as rs984136010, COSV50657337; called by muse, mutect2, varscan2
- ZNF385D | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV55768110; called by muse, mutect2, varscan2
- ZNF536 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62818547, COSV62821044; called by muse, mutect2
- ZNF546 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs775355670, COSV61258805; called by muse, mutect2, varscan2
- ADCY10 | c.1962_1974del p.W654* | Frame Shift Del (DEL) | VAF 53/208 reads (25%) | called by mutect2, pindel, varscan2
- FRAS1 | c.2189_2190del p.T730Rfs*27 | Frame Shift Del (DEL) | VAF 92/319 reads (29%) | called by pindel, varscan2
- NOMO1 | c.419_420dup p.P141Sfs*12 | Frame Shift Ins (INS) | VAF 87/715 reads (12%) | called by mutect2, pindel, varscan2
- SOX9 | c.185dup p.E63Gfs*189 | Frame Shift Ins (INS) | VAF 64/190 reads (34%) | called by mutect2, pindel, varscan2
- SOX9 | c.432-13_452del p.X144_splice | Splice Site (DEL) | VAF 50/322 reads (16%) | called by mutect2, pindel
- TUFT1 | c.525_534del p.V176Cfs*59 | Frame Shift Del (DEL) | VAF 73/212 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB41 | c.1610_1611dup p.E538* | Frame Shift Ins (INS) | VAF 67/221 reads (30%) | called by mutect2, pindel, varscan2
- ABCB8 | c.1140G>A p.G380= (on ENST00000297504 / NM_001282291.2; = p.G363= on NM_007188.5) | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as rs1328828785, COSV52508563; called by muse, mutect2, varscan2
- ACHE | c.243G>A p.P81= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs747887610, COSV53816477; called by muse, mutect2, varscan2
- AFF3 | c.3030G>A p.S1010= | Silent (SNP) | VAF 73/273 reads (27%) | catalogued as rs747852637, COSV57851113; called by muse, mutect2, varscan2
- ALOX12B | c.1521T>C p.N507= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV59875023; called by muse, mutect2, varscan2
- ATR | c.3507T>C p.S1169= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as COSV100638453; called by muse, mutect2
- BNC2 | c.2961G>A p.G987= | Silent (SNP) | VAF 99/239 reads (41%) | catalogued as COSV66171986; called by muse, mutect2, varscan2
- CACNG7 | c.612C>T p.Y204= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as COSV55816333; called by muse, mutect2, varscan2
- CD200R1 | c.141T>C p.T47= (on ENST00000471858 / NM_170780.3; = p.T70= on NM_138806.4) | Silent (SNP) | VAF 91/287 reads (32%) | catalogued as COSV99867623; called by muse, mutect2, varscan2
- DNASE1 | c.513C>T p.D171= | Silent (SNP) | VAF 64/187 reads (34%) | catalogued as rs770091885, COSV55913450; called by muse, mutect2, varscan2
- EVPL | c.3792C>T p.P1264= | Silent (SNP) | VAF 62/185 reads (34%) | catalogued as rs780250878, COSV56909102; called by muse, mutect2, varscan2
- GAB2 | c.1602C>T p.T534= (on ENST00000361507 / NM_080491.3; = p.T496= on NM_012296.3) | Silent (SNP) | VAF 32/378 reads (8%) | catalogued as rs1475283631, COSV100416537, COSV60869182; called by muse, mutect2
- HSPA14 | c.1212G>A p.V404= | Silent (SNP) | VAF 20/173 reads (12%) | catalogued as rs1468050966, COSV65684843; called by muse, mutect2, varscan2
- KCNQ5 | c.2280G>T p.L760= | Silent (SNP) | VAF 66/178 reads (37%) | catalogued as COSV59674888; called by muse, mutect2, varscan2
- KRT81 | c.54C>T p.C18= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs770430502, COSV59808881; called by muse, mutect2, varscan2
- MAS1 | c.516C>T p.I172= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as rs201944237, COSV53121903; called by muse, mutect2, varscan2
- NIM1K | c.144C>T p.F48= | Silent (SNP) | VAF 55/139 reads (40%) | catalogued as rs370653085; called by muse, mutect2, varscan2
- OGDH | c.1263C>T p.Y421= | Silent (SNP) | VAF 252/535 reads (47%) | catalogued as rs759170384, COSV56054577; called by muse, mutect2, varscan2
- PCDH10 | c.1203G>A p.V401= | Silent (SNP) | VAF 45/158 reads (28%) | catalogued as COSV52092106, COSV52100427; called by muse, mutect2, varscan2
- PCDH11X | c.933C>T p.I311= | Silent (SNP) | VAF 64/198 reads (32%) | catalogued as COSV100013769; called by muse, mutect2, varscan2
- PCDHA3 | c.1443C>T p.D481= | Silent (SNP) | VAF 219/559 reads (39%) | catalogued as rs782385485, COSV63538919; called by muse, mutect2, varscan2
- PIK3R1 | c.717G>A p.T239= | Silent (SNP) | VAF 105/316 reads (33%) | catalogued as rs745860837, COSV57135736; called by muse, mutect2, varscan2
- PPAT | c.18G>A p.L6= | Silent (SNP) | VAF 97/276 reads (35%) | catalogued as rs1312175111, COSV51705893; called by muse, mutect2, varscan2
- ROR2 | c.1149C>T p.N383= | Silent (SNP) | VAF 67/189 reads (35%) | catalogued as rs564454687, COSV65222149, COSV65222243; called by muse, mutect2, varscan2
- RXFP3 | c.675C>T p.A225= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as rs1023157563, COSV57505258; called by muse, mutect2, varscan2
- SIM1 | c.1362G>A p.S454= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV53491165; called by muse, mutect2, varscan2
- SLC9A7 | c.939C>T p.H313= | Silent (SNP) | VAF 162/514 reads (32%) | catalogued as rs753424466, COSV60382454; called by muse, mutect2, varscan2
- TAB1 | c.987C>T p.A329= | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as rs138903748; called by muse, mutect2, varscan2
- TMEM184A | c.1104C>T p.S368= | Silent (SNP) | VAF 77/262 reads (29%) | catalogued as COSV52475042; called by muse, mutect2, varscan2
- TUBD1 | c.363C>T p.N121= | Silent (SNP) | VAF 66/211 reads (31%) | catalogued as COSV57873917; called by muse, mutect2, varscan2
- UTP14A | c.309G>T p.V103= | Silent (SNP) | VAF 120/382 reads (31%) | catalogued as COSV100928991; called by muse, mutect2, varscan2
- GLRXP3 | n.89A>C | RNA (SNP) | VAF 130/430 reads (30%) | called by muse, mutect2, varscan2
